Somatic mutation profile of tumor specimen TCGA-14-1829-01A (aliquot TCGA-14-1829-01A-01W-0643-08) from TCGA case TCGA-14-1829, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.3 years (20,929 days).
Specimen TCGA-14-1829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf70308f-c84e-407e-ac11-24e35d80db8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1829-10A (Blood Derived Normal), aliquot TCGA-14-1829-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e2bc46b-82c5-449d-bffc-241bd9899ed5

The open-access MAF lists 69 somatic variants for this specimen: 51 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 40, Silent 18, Frame Shift Ins 6, Splice Region 2, Nonstop Mutation 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 18/163 reads (11%) | catalogued as rs767549806; called by mutect2, varscan2
- AKR1B10 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1562928667, COSV62055800; called by muse, mutect2, varscan2
- ANGPTL7 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); catalogued as rs781519687; called by muse, mutect2, varscan2
- BCAS1 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as COSV65085066; called by muse, mutect2
- BTNL3 | c.1200dup p.S401Qfs*14 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs757227190; called by mutect2, varscan2
- CDC42BPB | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 66/101 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs771452351, COSV63477320; called by muse, varscan2
- CEP152 | c.1174-1G>A p.X392_splice | Splice Site (SNP) | VAF 12/25 reads (48%) | catalogued as COSV57860632; called by muse, mutect2, varscan2
- CNTNAP1 | c.2266C>A p.Q756K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs931779390, COSV52851459; called by muse, mutect2, varscan2
- DPPA4 | c.912A>C p.E304D | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV59511048; called by muse, mutect2
- EBF2 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.382); catalogued as COSV68778693; called by muse, mutect2, varscan2
- ETF1 | c.864A>G p.G288= | Splice Region (SNP) | VAF 37/80 reads (46%) | catalogued as rs776841173, COSV62127596; called by muse, mutect2, varscan2
- EXOSC10 | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58666002; called by muse, mutect2, varscan2
- FBXO42 | c.1453dup p.R485Pfs*28 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | catalogued as rs747210971; called by pindel, varscan2
- FNIP1 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV57200669; called by muse, mutect2, varscan2
- GFRAL | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61232039; called by muse, mutect2
- GPR37 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs754836352, COSV58257537; called by muse, mutect2, varscan2
- GRM1 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.014); catalogued as rs1337360562; called by muse, varscan2
- IGSF11 | c.259dup p.R87Pfs*5 (on ENST00000393775 / NM_001015887.3; = p.R86Pfs*5 on NM_152538.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs756300941; called by pindel, varscan2
- LY96 | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV53025729; called by muse, mutect2, varscan2
- MAN2B1 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV55472810; called by muse, mutect2, varscan2
- NLRP12 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs777735292, COSV60749384; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 28/110 reads (25%) | catalogued as rs754860965; called by mutect2, varscan2
- NRXN3 | c.1744G>A p.A582T (on ENST00000557594 / NM_001272020.2; = p.A1006T on NM_004796.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55333949; called by muse, mutect2, varscan2
- OR4D10 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs761012920, COSV73260081; called by muse, varscan2
- PCDHB6 | c.1148T>C p.I383T | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as rs142117819; called by muse, mutect2, varscan2
- PCDHB7 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as rs544763939, COSV50754257; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2875G>T p.A959S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as COSV62783668, COSV62784945; called by muse, mutect2, varscan2
- RCOR2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV56851321; called by muse, mutect2
- SCAF1 | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.677); catalogued as rs760814202; called by muse, mutect2
- SLC17A8 | c.1391G>A p.C464Y | Missense Mutation (SNP) | VAF 77/372 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60124615; called by muse, mutect2, varscan2
- SLC5A11 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61741729; called by muse, mutect2
- TAF2 | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | catalogued as COSV65418740; called by muse, mutect2, varscan2
- TCHH | c.4865G>A p.R1622H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV100914884, COSV64275588; called by muse, mutect2, varscan2
- TREML1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs1158030899, COSV58294929; called by muse, mutect2
- URGCP | c.1939C>A p.P647T (on ENST00000453200 / NM_001077663.3; = p.P638T on NM_017920.4) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56249012; called by muse, varscan2
- URGCP | c.1028C>G p.S343C (on ENST00000453200 / NM_001077663.3; = p.S334C on NM_017920.4) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56249032; called by muse, mutect2, varscan2
- URGCP | c.294C>G p.I98M (on ENST00000453200 / NM_001077663.3; = p.I89M on NM_017920.4) | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56249050; called by muse, mutect2, varscan2
- ZBTB7C | c.960dup p.P321Afs*141 | Frame Shift Ins (INS) | VAF 16/170 reads (9%) | catalogued as rs751294936; called by mutect2, varscan2
- ALAS1 | c.1922G>T p.*641Lext*2 | Nonstop Mutation (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- CEP104 | c.941G>C p.S314T | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); called by muse, mutect2
- CHP1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 76/1587 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.837); called by muse, mutect2
- DDX41 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 144/246 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DEPDC1 | c.588C>T p.I196= | Splice Region (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- ENDOD1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.829); called by muse, varscan2
- FYCO1 | c.575G>T p.W192L | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- MAZ | c.581T>A p.L194Q | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- PKHD1 | c.5170G>A p.G1724R | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PODNL1 | c.1472C>A p.S491Y | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.193); called by muse, mutect2
- RAB8B | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SYT14 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- TTN | c.5869C>A p.L1957I (on ENST00000591111; = p.L1911I on NM_003319.4) | Missense Mutation (SNP) | VAF 26/498 reads (5%) | PolyPhen benign (0.028); called by muse, mutect2
- AASDH | c.948C>T p.A316= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- ABCF3 | c.1665G>A p.L555= | Silent (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- BNC2 | c.1710T>A p.P570= | Silent (SNP) | VAF 84/257 reads (33%) | called by muse, varscan2
- EPS15 | c.2690G>A p.*897= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- GRID1 | c.438C>T p.P146= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as rs764843634, COSV60012496; called by muse, mutect2, varscan2
- HHIPL2 | c.351C>T p.Y117= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1291388394, COSV58563595; called by muse, mutect2, varscan2
- KRT37 | c.411C>T p.L137= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs762388047, COSV56656819; called by muse, mutect2, varscan2
- LTBR | c.781C>T p.L261= | Silent (SNP) | VAF 30/270 reads (11%) | catalogued as COSV57439165; called by muse, mutect2, varscan2
- NOX5 | c.93G>A p.V31= | Silent (SNP) | VAF 103/154 reads (67%) | called by muse, mutect2, varscan2
- NUP133 | c.1932C>T p.A644= | Silent (SNP) | VAF 52/131 reads (40%) | catalogued as rs374819603, COSV54572485; called by muse, mutect2, varscan2
- PIK3CG | c.120C>T p.I40= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs1004936166, COSV63249566; called by muse, mutect2, varscan2
- SIAH3 | c.294C>T p.H98= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs773723798, COSV68552240; called by muse, mutect2, varscan2
- SLIT2 | c.2160T>C p.S720= | Silent (SNP) | VAF 116/380 reads (31%) | catalogued as COSV56577313; called by muse, mutect2, varscan2
- TLL2 | c.1377G>A p.A459= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs750004312, COSV63573275; called by muse, mutect2, varscan2
- UBIAD1 | c.414C>G p.L138= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV65147856; called by muse, mutect2, varscan2
- URGCP | c.2025C>G p.V675= (on ENST00000453200 / NM_001077663.3; = p.V666= on NM_017920.4) | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV56248988; called by muse, varscan2
- VPS54 | c.2268C>T p.C756= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- ZNF287 | c.2238C>T p.N746= | Silent (SNP) | VAF 32/434 reads (7%) | called by muse, mutect2
